Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V4, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V4-01A (Primary Tumor).

[page 1 of 4]
& Neck
And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

year old with papillary thyroid ca.

Specimens Submitted:

- 1: Right paratracheal tissue (fs)
- 2: R/O left lower parathyroid (fs)
- 3: Left paratracheal lymph node (fs)
- 4: Total thyroid
- 5: Additional left paratracheal tissue

DIAGNOSIS:

1. Right paratracheal tissue, biopsy:
- Benign fibroadipose tissue
2. R/O left lower parathyroid, biopsy:
- Benign enlarged hypercellular parathyroid gland (weight: 0.92 grams)
3. Left paratracheal lymph node, biopsy:
- Micrometastatic papillary carcinoma to lymph node
- Lymph node measures 0.6 cm in greatest size with micrometastatic focus less than 0.05 cm
- No extranodal extension seen

4. Total thyroid:

Tumor Type:

Papillary carcinoma, tall cell variant > 50% Tall cell features per TSS / lw

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.3 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades: perithyroid skeletal muscle

Surgical Margins:

ICD-O-3

carcinoma, papillary, tall cell

834413

Site: thyroid, NOS

C73.9 5-2-12
RW

[page 2 of 4]
Free of tumor

Tumor Multicentricity:

- Separate papillary carcinoma tall cell variant 1cm in the right lobe and 0.2 cm papillary microcarcinoma in left lobe

Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not Identified

5. Additional left paratracheal tissue, biopsy:

- One lymph node positive for micrometastatic papillary carcinoma (1/1)
- The metastatic lymph node is 0.3 cm with metastatic focus 0.1 cm
- No extranodal extension seen

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "right paratracheal tissue" and consists of fragment of tan-pink tissue measuring 0.8 x 0.6 x 0.5 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

2. The specimen is received fresh for frozen section consultation, labeled "r/o left lower parathyroid (weigh specimen)" and consists of a tan red fragment of tissue measuring 2.1x1.5x0.3 cm and weighs 0.92 grams. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

3. The specimen is received fresh for frozen section consultation, labeled "left peritracheal lymph node" and consists of one lymph node measuring 1.0x0.8x0.4 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

4). The specimen is received fresh, labeled "Total thyroid suture marks right lobe" and consists of a thyroid weighing 29.5 g. The right lobe measures 4.5 x 3.3 x 2.4 cm, the left lobe measures 4.1 x 2.9 x 1.7 cm and the isthmus measures 1.6 x 1.5 x 0.8 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Three encapsulated nodules are identified in the left lobe, measuring 0.8 x 0.8 x 0.6, 1.3 x 1.3 x 0.8, and 1.6 x 1.5 x 1.4 cm. The left lobe nodules are arbitrarily designated; smallest left lobe nodule N1, the middle N2, and the largest N3. Nodule N2 and N3 are adjacent, located in the upper pole. N3 is focally calcified. N1 is located in the lower pole of the left lobe. Sectioning through the remaining tissue reveals four encapsulated nodules in the right lobe ranging from 0.5 x 0.4 x 0.4 to 2.9 x 1.7 x 1.0cm. The right

[page 3 of 4]
lobe nodules are arbitrarily designated from smallest to largest N4-N7. The largest nodule (N7) is located in the lower pole, and N7 is located at the superior pole of the right lobe. N5 is focally calcified and abuts the anterior capsule. At the junction of the left lower pole and isthmus is a 2.0 x 1.5 x .0 cm encapsulated gelatinous nodule. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for and a photograph has been taken. The remaining tissue is serially sectioned and * submitted.

Summary of sections:

AN--adjacent left lobe nodules N2 and N3
N1--smallest left lobe nodule
N2--left lobe nodule
N3--largest left lobe nodule submitted)
N4--smallest right lobe nodule
N5--calcified nodule
N6--superior pole nodule
N7--largest right lobe nodule
LI-- lower left lobe to isthmus nodule
RL-- representative right lobe
LL--representative left lobe
IS - isthmus representative

6). The specimen is received in formalin, labeled "Additional left paratracheal tissue" and consists of a 1 x 0.6 x 0.4 cm fragment of tan soft tissue. Entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Right paratracheal tissue (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: R/O left lower parathyroid (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Left paratracheal lymph node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 4: Total thyroid

Block	Sect. Site	PCs
3	AN	3
2	IS	2
3	LI	4
2	LL	2
2	N1	2
2	N2	4
3	N3	3
1	N4	3
2	N5	3
2	N6	4
4	N7	4
2	RL	2

Part 5: Additional left paratracheal tissue

[page 4 of 4]
Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Right paratracheal tissue (fs): Benign
Permanent Diagnosis: same
2. Frozen Section Diagnosis: R/O left lower parathyroid (fs): Hypercellular parathyroid tissue (0.92 grams)
Permanent Diagnosis: same
3. Frozen Section Diagnosis: Left paratracheal lymph node (fs): Lymph node with micrometastasis
Permanent Diagnosis: same

Source: NCI Genomic Data Commons file 260e50b7-31cc-41a4-932b-5b87f0417ea4 (TCGA-DJ-A3V4.F2C37C78-F561-46CE-809A-AA66BB580006.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).